Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4PA, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4PA-01A (Primary Tumor).

Gross Description: Lung up to 23x14x6 cm in size, with white dense tumor up to 5x3 cm in size.

Microscopic Description: Squamous non-keratinizing carcinoma of the lung, G2.

Five bronchopulmonary lymph nodes demonstrated reactive changes.

Fragment of the bronchus is of normal structure.

Diagnosis Details: Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent,
Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 3 x 0 x 5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/5 positive for metastasis (Bronchopulmonary 0/5)

Lymphatic invasion: Not specified

Venous invasion: Absent

ICD - 0-3
carcinoma, squamous cell,
nonkeratinizing, NOS 8072/3
Site: lung, lower lobe c34.3
pw
10/5/12

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- lower

Reviewed/Initialed:	pw 10/5/12	

Source: NCI Genomic Data Commons file fc30ba95-8d23-4b20-8748-f95c36367a33 (TCGA-85-A4PA.4CFDEC28-F3F6-484F-8C51-29429D7927DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).